Somatic mutation profile of tumor specimen TCGA-EA-A3HT-01A (aliquot TCGA-EA-A3HT-01A-61D-A21Q-09) from TCGA case TCGA-EA-A3HT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 68.8 years (25,138 days).
Specimen TCGA-EA-A3HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a1616a3-3ccd-45df-8d6e-d04e263992ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3HT-10A (Blood Derived Normal), aliquot TCGA-EA-A3HT-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba4a8979-df4d-46e3-8673-82be2d397041

The open-access MAF lists 121 somatic variants for this specimen: 79 protein-altering or splice-affecting, 34 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 34, Nonsense Mutation 6, RNA 3, 3'Flank 2, Splice Site 2, Intron 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as rs80338964, CM004255, COSV61688328; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.3148G>A p.G1050R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537343964, COSV58683012; called by muse, mutect2, varscan2
- ANKFN1 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV59447385; called by muse, mutect2
- AQP10 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV100269856; called by muse, mutect2, varscan2
- ARPP21 | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV51797789; called by muse, mutect2
- ATP2C1 | c.2841G>C p.E947D (on ENST00000507488 / NM_001378511.1; = p.E882Q on NM_001001485.2) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV53908663; called by muse, mutect2, varscan2
- ATP7A | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58446404; called by muse, mutect2, varscan2
- BAG3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV64842018; called by muse, mutect2, varscan2
- BIRC5 | c.250T>A p.C84S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051165; called by muse, varscan2
- BIRC5 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV56956469; called by muse, varscan2
- BIVM-ERCC5 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); catalogued as COSV57279612; called by muse, mutect2, varscan2
- CDH4 | c.2633G>T p.G878V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100848218; called by muse, mutect2
- CFHR5 | c.1703G>A p.C568Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56821960; called by muse, mutect2
- CLTCL1 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV54230660; called by muse, mutect2, varscan2
- COX5A | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59279133; called by muse, mutect2, varscan2
- CTSE | c.661T>C p.S221P (on ENST00000360218; = p.S216P on NM_001910.4) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782052477, COSV63060732; called by muse, mutect2, varscan2
- CXCR4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as rs1558837039, COSV54012449; called by muse, mutect2, varscan2
- CYP2C19 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs118203757; ClinVar: drug response; called by muse, mutect2, varscan2
- EEF2 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58579495; called by muse, mutect2, varscan2
- EHD1 | c.1142C>A p.T381K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV57734703, COSV57736616; called by muse, mutect2, varscan2
- EHMT2 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV64996005; called by muse, varscan2
- GASK1B | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV56707329; called by muse, mutect2, varscan2
- GIPR | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs1250456462, COSV99624313; called by muse, mutect2
- GOLGA5 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV50833009; called by muse, mutect2, varscan2
- GRAMD1C | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV63982756; called by muse, mutect2, varscan2
- GRAMD2A | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV59032797, COSV59033703; called by muse, mutect2, varscan2
- HELZ2 | c.7805A>G p.Q2602R (on ENST00000467148 / NM_001037335.2; = p.Q2033R on NM_033405.3) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV64442773; called by muse, mutect2, varscan2
- IGSF1 | c.2519G>T p.G840V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63837488; called by muse, mutect2, varscan2
- ITCH | c.2399G>C p.R800P (on ENST00000262650 / NM_001257137.3; = p.R759P on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52931952, COSV52933921; called by muse, mutect2, varscan2
- ITIH6 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs141798202, COSV54489131; called by muse, mutect2, varscan2
- KAT6A | c.5972G>A p.G1991D | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV55906038; called by muse, mutect2, varscan2
- KL | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV66308788; called by muse, mutect2, varscan2
- LETM1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as rs141023040; called by muse, mutect2, varscan2
- LGALS12 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55370273; called by muse, mutect2, varscan2
- LIN9 | c.1279A>T p.K427* (on ENST00000366808 / NM_001270410.2; = p.K372* on NM_173083.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV60245098; called by muse, mutect2, varscan2
- LRPPRC | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs372127413, COSV53238316; called by muse, mutect2, varscan2
- MACC1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60542988; called by muse, mutect2, varscan2
- MADD | c.4138T>A p.S1380T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV60624098; called by muse, mutect2, varscan2
- MAGEF1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1435687771, COSV58633743; called by muse, mutect2, varscan2
- MAN2A1 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54851579; called by muse, mutect2, varscan2
- MAPK1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53185671; called by muse, mutect2, varscan2
- MAST4 | c.4787C>T p.A1596V (on ENST00000403625 / NM_001164664.2; = p.A1407V on NM_015183.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV55125190; called by muse, mutect2
- MED1 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.284); catalogued as rs752110530, COSV56124854; called by muse, mutect2, varscan2
- NDUFB11 | c.356G>A p.R119H (on ENST00000377811 / NM_001135998.3; = p.R129H on NM_019056.6) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs782460503, COSV52102129; called by muse, mutect2, varscan2
- NSDHL | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs782180567, COSV64743942; called by muse, mutect2, varscan2
- OR10G8 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs774001236, COSV70908401; called by muse, mutect2, varscan2
- OR8J3 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100040865, COSV56880753; called by muse, mutect2, varscan2
- OR8K5 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2, varscan2
- PCDHB2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52035165; called by muse, mutect2, varscan2
- PCDHB9 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as rs782419413; called by muse, mutect2, varscan2
- PICALM | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV62670762, COSV62671631; called by muse, mutect2, varscan2
- POT1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV62927755, COSV62930107, COSV62930155; called by muse, mutect2, varscan2
- POTEF | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV100665054, COSV62541286; called by muse, mutect2, varscan2
- PRIMA1 | c.229+1G>A p.X77_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60263745; called by muse, mutect2, varscan2
- RAP1GDS1 | c.146G>A p.G49E (on ENST00000408927 / NM_001100427.2; = p.G50E on NM_021159.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377518587; called by mutect2, varscan2
- RBL1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV60329944; called by muse, mutect2, varscan2
- REPS1 | c.2110C>T p.R704* (on ENST00000450536 / NM_001286611.2; = p.R703* on NM_031922.4) | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as rs1256246588, COSV57810756; called by muse, mutect2, varscan2
- RRM2B | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV52566793; called by muse, mutect2, varscan2
- RXRB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV59495758, COSV59496898; called by muse, mutect2, varscan2
- SMARCAL1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as COSV61921100; called by muse, mutect2, varscan2
- SOCS4 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.922); catalogued as rs368652531; called by muse, mutect2, varscan2
- SYTL4 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775187605, COSV52167693; called by muse, mutect2, varscan2
- TARBP1 | c.2764G>C p.V922L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs563481719, COSV50184535; called by muse, mutect2, varscan2
- TEX15 | c.4073G>A p.R1358K (on ENST00000256246; = p.R1741K on NM_001350162.2) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV56353430, COSV99820545; called by muse, mutect2
- THSD7B | c.4196G>A p.R1399H (on ENST00000272643; = p.R1397H on NM_001316349.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as rs565075278, COSV55686958, COSV55737827; called by muse, mutect2, varscan2
- TM4SF5 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54496643, COSV99564616; called by muse, mutect2, varscan2
- TREX2 | c.265G>A p.D89N (on ENST00000334497; = p.D46N on NM_080701.3) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs781813481, COSV57849139; called by muse, mutect2, varscan2
- UBE2E1 | c.153-1G>A p.X51_splice | Splice Site (SNP) | VAF 63/109 reads (58%) | catalogued as COSV60667772; called by muse, mutect2, varscan2
- UGT2B15 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV57733794; called by muse, mutect2
- WASF3 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs751195518, COSV100098122, COSV58965893; called by muse, varscan2
- WNK1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV60033194; called by muse, mutect2, varscan2
- ZEB2 | c.1049C>A p.T350K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV57953916, COSV57956804; called by muse, mutect2, varscan2
- ZNF112 | c.1858C>T p.R620W (on ENST00000337401 / NM_001083335.2; = p.R614W on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs770383816, COSV61620053; called by muse, mutect2, varscan2
- ZNF236 | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV53488338; called by muse, mutect2, varscan2
- ZNF791 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV58480942; called by muse, mutect2, varscan2
- GDF10 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TUBGCP5 | c.2564T>G p.L855R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF493 | c.-127_-126del | Splice Region (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- ACAD10 | c.63G>A p.L21= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV58156738; called by muse, mutect2, varscan2
- AHNAK | c.1299G>A p.K433= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV57213364; called by muse, mutect2, varscan2
- ATP4A | c.2379G>A p.K793= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV52868031, COSV99383084; called by muse, mutect2, varscan2
- C5 | c.441G>A p.S147= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs376535022; called by muse, mutect2, varscan2
- CALHM2 | c.183C>T p.I61= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs767823366, COSV53294773; called by muse, mutect2, varscan2
- CCDC171 | c.1302G>A p.S434= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs527328493, COSV52641634; called by muse, mutect2, varscan2
- CDK2AP2 | c.240C>T p.V80= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56873664; called by muse, mutect2, varscan2
- COLEC11 | c.408C>T p.L136= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs773675344, COSV52593775; called by muse, mutect2, varscan2
- DSP | c.6279C>T p.I2093= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV65792722, COSV65792749; called by muse, mutect2, varscan2
- EGR1 | c.21G>A p.E7= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53519375; called by muse, mutect2, varscan2
- EHMT2 | c.1893C>T p.A631= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV64995995; called by muse, varscan2
- FAM160B2 | c.1635C>G p.P545= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs752701549, COSV57158517, COSV57159232; called by muse, mutect2, varscan2
- HAX1 | c.237C>T p.F79= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs761531560, COSV55172661; called by muse, mutect2, varscan2
- HFM1 | c.2238T>C p.I746= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99645073; called by muse, mutect2, varscan2
- HLA-DPB1 | c.747G>A p.R249= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs759486323, COSV101330953, COSV69603243; called by muse, mutect2, varscan2
- HPCAL4 | c.246C>T p.F82= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs759823943, COSV65716276; called by muse, mutect2, varscan2
- KCNH6 | c.1068C>T p.F356= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs774234991, COSV59003343; called by muse, mutect2, varscan2
- MLPH | c.516C>A p.G172= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs765978825, COSV52820305; called by muse, mutect2, varscan2
- OR5M1 | c.282C>T p.Y94= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs371477399; called by muse, mutect2, varscan2
- PCDHA3 | c.1698G>A p.L566= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV63541405; called by muse, mutect2, varscan2
- POGK | c.36G>A p.L12= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV63311593; called by muse, mutect2, varscan2
- REG1A | c.42G>A p.L14= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1235055407, COSV52068767, COSV52069858, COSV52070482; called by muse, mutect2, varscan2
- RNF213 | c.9327C>T p.Y3109= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs778158475, COSV60397432; called by muse, mutect2, varscan2
- RXRB | c.1601G>A p.*534= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV59496893; called by muse, mutect2, varscan2
- SGTA | c.225G>A p.L75= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55593984; called by muse, mutect2
- SKA1 | c.306G>A p.Q102= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99552657; called by muse, mutect2, varscan2
- SLC22A4 | c.1569G>A p.Q523= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs146182196; called by muse, mutect2, varscan2
- SLC7A6 | c.1116C>T p.F372= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV50450089; called by muse, mutect2, varscan2
- SPATA32 | c.576C>T p.L192= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV59303764; called by muse, mutect2, varscan2
- SSR4 | c.93C>T p.I31= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1557072497, COSV54207610; called by muse, mutect2, varscan2
- THOC5 | c.903C>T p.F301= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100803372; called by muse, mutect2, varscan2
- TRIM46 | c.579C>T p.F193= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV55278854; called by muse, mutect2, varscan2
- VLDLR | c.582C>T p.G194= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs148012674; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZMIZ1 | c.3084G>A p.E1028= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs746263887, COSV57895535; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499010 C>T | 5'Flank (SNP) | VAF 9/34 reads (26%) | catalogued as rs376520805; called by muse, mutect2, varscan2
- C11orf40 | n.103G>A | RNA (SNP) | VAF 8/45 reads (18%) | catalogued as rs1258166867, COSV56890568; called by muse, mutect2, varscan2
- CDC37P1 | n.877G>A | RNA (SNP) | VAF 31/98 reads (32%) | catalogued as rs745597348; called by muse, mutect2, varscan2
- COPS9 | chr2:240126672 G>C | 3'Flank (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56228164; called by muse, mutect2, varscan2
- COPS9 | chr2:240126832 G>A | 3'Flank (SNP) | VAF 18/47 reads (38%) | catalogued as COSV56228171; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-36C>T | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100024642, COSV100024722; called by muse, varscan2
- NXF5 | n.903A>G | RNA (SNP) | VAF 36/189 reads (19%) | catalogued as COSV53790955; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+30T>C | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65367018; called by muse, mutect2, varscan2
